Somatic mutation profile of tumor specimen TCGA-EE-A20C-06A (aliquot TCGA-EE-A20C-06A-11D-A196-08) from TCGA case TCGA-EE-A20C, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 71.5 years (26,129 days).
Specimen TCGA-EE-A20C-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ca0615f-4ca0-4d3a-b86b-ca1d76a00eb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A20C-10A (Blood Derived Normal), aliquot TCGA-EE-A20C-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de662663-2cbc-4f0b-b138-c56e484f1809

The open-access MAF lists 2,516 somatic variants for this specimen: 1,621 protein-altering or splice-affecting, 845 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,451, Silent 845, Nonsense Mutation 99, Splice Region 28, Splice Site 24, Intron 20, RNA 13, Frame Shift Del 13, 3'UTR 6, 3'Flank 6, Frame Shift Ins 3, 5'Flank 3.

Variants (750 of 2,516; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT3 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397514606, COSV55605820, COSV55624598; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASL | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199938613, CM141220, COSV100508883; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ASPM | c.9319C>T p.R3107* | Nonsense Mutation (SNP) | VAF 24/32 reads (75%) | catalogued as rs199422187, CM092387, COSV54123750; ClinVar: pathogenic; called by mutect2, varscan2
- ATF6 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761357250, CM156874, COSV63405743; ClinVar: pathogenic; called by mutect2, varscan2
- CASR | c.1421G>A p.R474K (on ENST00000490131; = p.R551K on NM_000388.4) | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs1060502861, HM040041, COSV56133780; ClinVar: likely pathogenic; called by muse, varscan2
- CASR | c.2228C>T p.S743F (on ENST00000490131; = p.S820F on NM_000388.4) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs104893710, CM021251, COSV56133807; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2263T>A p.L755M | Missense Mutation (SNP) | VAF 23/51 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519890, COSV54062219, COSV54066696; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FRMD4B | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 32/48 reads (67%) | hotspot (GDC flag); SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV68328045; called by muse, mutect2, varscan2
- MYBPC1 | c.877C>T p.R293* (on ENST00000550270 / NM_206820.2; = p.R318* on NM_002465.4) | Nonsense Mutation (SNP) | VAF 10/14 reads (71%) | catalogued as rs397515422, CM129132, COSV62250776; ClinVar: pathogenic; called by mutect2, varscan2
- MYO18B | c.3053C>T p.P1018L | Missense Mutation (SNP) | VAF 33/70 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as rs753198702, COSV100123566, COSV59124221; called by muse, mutect2, varscan2
- NLRP3 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs121908153, CM021071, CM076355, COSV60219065; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 90/133 reads (68%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PCSK5 | c.2771G>A p.W924* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | hotspot (GDC flag); catalogued as COSV70451329; called by muse, mutect2, varscan2
- PKHD1 | c.9718C>T p.R3240* | Nonsense Mutation (SNP) | VAF 16/31 reads (52%) | catalogued as rs1057516577, CM032331, COSV61858467; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- SYT13 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 42/70 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen possibly damaging (0.858); catalogued as rs868559206, COSV50072436, COSV50073637; called by muse, mutect2, varscan2
- ABCA1 | c.4432C>T p.P1478S | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV66063384; called by muse, mutect2, varscan2
- ABCA10 | c.1682T>C p.F561S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.67); catalogued as COSV52217614; called by muse, mutect2, varscan2
- ABCA12 | c.1516C>T p.P506S (on ENST00000272895 / NM_173076.3; = p.P188S on NM_015657.3) | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV55947956; called by muse, mutect2, varscan2
- ABCA12 | c.898T>G p.Y300D | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV55947967; called by muse, mutect2, varscan2
- ABCA3 | c.2112G>A p.W704* | Nonsense Mutation (SNP) | VAF 40/106 reads (38%) | catalogued as COSV57048804; called by muse, varscan2
- ABCA9 | c.4649C>T p.S1550F | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as COSV60619771; called by muse, varscan2
- ABCC1 | c.2809G>A p.A937T | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1332083957, COSV100580410, COSV60679209; called by muse, varscan2
- ABCD2 | c.308A>G p.E103G | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58049089; called by muse, mutect2, varscan2
- ABCE1 | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 70/141 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV56846002; called by mutect2, varscan2
- ABRAXAS2 | c.264A>T p.R88S | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV53715709; called by mutect2, varscan2
- AC100868.1 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.155); catalogued as COSV51837280; called by muse, mutect2, varscan2
- AC100868.1 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs372434452, COSV51839518; called by mutect2, varscan2
- AC244197.3 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 28/28 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); catalogued as rs782817492, COSV61711016; called by muse, mutect2, varscan2
- ACADL | c.661C>T p.H221Y | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs534447533, COSV52051986; called by mutect2, varscan2
- ACAN | c.4411C>T p.P1471S | Missense Mutation (SNP) | VAF 87/90 reads (97%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs376237216, COSV61355063; called by muse, mutect2, varscan2
- ACAP1 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1380039244, COSV50134008; called by muse, mutect2, varscan2
- ACAP2 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58748927; called by muse, mutect2, varscan2
- ACO2 | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53440717; called by muse, mutect2, varscan2
- ACOT12 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.809); catalogued as rs758717890, COSV100296804, COSV100296910; called by muse, mutect2, varscan2
- ACSM2B | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369392849; called by mutect2, varscan2
- ACSM4 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101257149; called by muse, mutect2
- ACTG2 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.433); catalogued as COSV61827330; called by muse, mutect2, varscan2
- ADAD2 | c.1451G>A p.G484D (on ENST00000315906 / NM_001145400.2; = p.G566D on NM_139174.4) | Missense Mutation (SNP) | VAF 35/39 reads (90%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs775453617, COSV51892275; called by muse, mutect2, varscan2
- ADAM29 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63659758; called by muse, mutect2, varscan2
- ADAM29 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.685); catalogued as COSV63659764; called by muse, mutect2, varscan2
- ADAMTS12 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.45); catalogued as COSV61254507; called by muse, varscan2
- ADAMTS12 | c.2810C>T p.S937F | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV61254513; called by muse, varscan2
- ADAMTS12 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs537162064, COSV61254518; called by muse, mutect2, varscan2
- ADAMTS12 | c.311T>A p.F104Y | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV61254525; called by muse, mutect2, varscan2
- ADAMTS19 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV50731325, COSV50737127; called by muse, mutect2, varscan2
- ADAMTS2 | c.2858C>T p.S953F | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV52371211; called by muse, mutect2, varscan2
- ADAMTS20 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV67125622, COSV67131641; called by mutect2, varscan2
- ADAMTSL2 | c.167G>A p.W56* | Nonsense Mutation (SNP) | VAF 36/62 reads (58%) | catalogued as COSV63203077; called by muse, mutect2, varscan2
- ADCY2 | c.1987A>T p.M663L | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs550831908, COSV57857084; called by muse, mutect2, varscan2
- ADCY8 | c.1396T>A p.Y466N | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53894869; called by muse, mutect2, varscan2
- ADGRB3 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369405391, COSV65394023; called by muse, mutect2, varscan2
- ADGRG4 | c.2409A>T p.E803D | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV54948445; called by mutect2, varscan2
- ADGRL4 | c.1633G>A p.V545I | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66058677; called by muse, mutect2, varscan2
- ADGRV1 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.705); catalogued as rs775156018, COSV101316537, COSV67977494; called by muse, mutect2, varscan2
- ADH1A | c.908C>A p.S303* | Nonsense Mutation (SNP) | VAF 78/134 reads (58%) | catalogued as COSV52924157, COSV52924976; called by muse, mutect2, varscan2
- ADH5 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56447094; called by muse, mutect2, varscan2
- ADPRHL1 | c.784A>G p.K262E | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.138); catalogued as COSV62909733; called by muse, mutect2, varscan2
- AGBL1 | c.2080C>T p.H694Y | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV66847341; called by mutect2, varscan2
- AGBL2 | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs568088440, COSV100101674; called by mutect2, varscan2
- AGO2 | c.1864C>T p.P622S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV55044757; called by muse, mutect2, varscan2
- AHNAK | c.13349C>T p.P4450L | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1252699104, COSV57202250; called by muse, mutect2, varscan2
- AHNAK2 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV60906472; called by muse, mutect2, varscan2
- AKAP6 | c.2726C>T p.P909L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV55203295; called by muse, mutect2, varscan2
- AKAP6 | c.3119C>T p.S1040L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.456); catalogued as rs750694931, COSV55203312, COSV55234652; called by mutect2, varscan2
- AKNAD1 | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.272); catalogued as COSV100645520; called by muse, mutect2, varscan2
- AKR1A1 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV61086155; called by muse, mutect2, varscan2
- AKR1C3 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV65909978; called by mutect2, varscan2
- AKR1C8P | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs868921765; called by muse, mutect2, varscan2
- AL645922.1 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54961533; called by muse, varscan2
- AL645922.1 | c.2156C>T p.S719F | Missense Mutation (SNP) | VAF 95/153 reads (62%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV54959013; called by muse, mutect2, varscan2
- ALB | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV55735411; called by muse, mutect2, varscan2
- ALG13 | c.415A>G p.I139V | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV52634706; called by muse, mutect2, varscan2
- ALG2 | c.635T>C p.V212A | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs1305858158, COSV53058627; called by muse, mutect2, varscan2
- ALPK1 | c.3314C>T p.P1105L | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV51581205; called by muse, mutect2, varscan2
- ALPK2 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV64489782; called by muse, mutect2, varscan2
- ALS2 | c.1475C>T p.S492F | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51883609, COSV51885889; called by muse, mutect2, varscan2
- AMTN | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV59488386; called by mutect2, varscan2
- AMY1C | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV100915189; called by mutect2, varscan2
- ANAPC2 | c.1540C>T p.L514F | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1413115326, COSV100119048; called by muse, mutect2, varscan2
- ANK2 | c.10045C>T p.P3349S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52143759; called by muse, mutect2, varscan2
- ANK3 | c.6840T>G p.F2280L | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV55042416; called by muse, mutect2, varscan2
- ANKRD11 | c.5118del p.T1707Rfs*12 | Frame Shift Del (DEL) | VAF 48/73 reads (66%) | catalogued as rs1567565668; called by mutect2, pindel, varscan2
- ANKRD17 | c.2071A>T p.T691S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.316); catalogued as COSV58214456; called by muse, mutect2, varscan2
- ANKRD26 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as COSV65792486; called by muse, mutect2, varscan2
- ANKRD27 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs760642564, COSV60128439; called by muse, mutect2, varscan2
- ANKRD30A | c.196C>T p.L66F (on ENST00000611781; = p.L10F on NM_052997.2) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1440280197, COSV64602921, COSV64617179; called by muse, mutect2, varscan2
- ANKRD30A | c.824G>A p.G275E (on ENST00000611781; = p.G219E on NM_052997.2) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.994); catalogued as rs1455673314, COSV100653516; called by muse, mutect2, varscan2
- ANKRD30A | c.2967G>A p.M989I (on ENST00000611781; = p.M933I on NM_052997.2) | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64602934; called by muse, mutect2, varscan2
- ANKRD35 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.969); catalogued as COSV62909397; called by muse, mutect2, varscan2
- ANKS4B | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV61138620; called by muse, mutect2, varscan2
- ANO2 | c.1549G>A p.D517N (on ENST00000356134 / NM_001278597.3; = p.D521N on NM_001278596.3) | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs369795691, COSV59006076; called by muse, mutect2, varscan2
- ANO4 | c.694G>A p.D232N (on ENST00000392977 / NM_001286615.2; = p.D197N on NM_178826.4) | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.357); catalogued as COSV54583680; called by muse, mutect2, varscan2
- ANPEP | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.034); catalogued as rs777473328, COSV55588967; called by muse, mutect2, varscan2
- ANTXR1 | c.728G>C p.G243A | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58008265; called by muse, mutect2, varscan2
- ANXA10 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as COSV63737862; called by muse, mutect2, varscan2
- AOX1 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV65979784; called by muse, mutect2, varscan2
- AP1M1 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99358378; called by mutect2, varscan2
- AP3B2 | c.3034C>T p.R1012W (on ENST00000261722; = p.R1006W on NM_004644.5) | Missense Mutation (SNP) | VAF 74/144 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs368331201; called by muse, mutect2, varscan2
- APCS | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 50/65 reads (77%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.849); catalogued as rs761743822, COSV54817068; called by muse, mutect2, varscan2
- APLP1 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.647); catalogued as COSV55701405; called by muse, mutect2, varscan2
- APOB | c.10615G>A p.D3539N | Missense Mutation (SNP) | VAF 120/286 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.267); catalogued as COSV51921474; called by muse, mutect2, varscan2
- APOB | c.7924C>T p.P2642S | Missense Mutation (SNP) | VAF 108/222 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51921485; called by muse, mutect2, varscan2
- APOB | c.538-1G>A p.X180_splice | Splice Site (SNP) | VAF 124/303 reads (41%) | catalogued as COSV51921495; called by muse, mutect2, varscan2
- APOBR | c.1048+5G>A | Splice Region (SNP) | VAF 20/31 reads (65%) | catalogued as rs1469786343, COSV60488397; called by muse, mutect2, varscan2
- APOE | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 119/259 reads (46%) | catalogued as COSV52984882; called by muse, mutect2, varscan2
- AQP1 | c.508C>T p.L170F | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100310917, COSV61266221; called by muse, mutect2, varscan2
- AQP9 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs150714814; called by muse, mutect2, varscan2
- AQP9 | c.700T>C p.F234L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV54967264; called by muse, mutect2
- ARAP2 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as rs776369290, COSV58281912; called by muse, mutect2
- ARAP2 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV58281921; called by mutect2, varscan2
- ARFGEF2 | c.353T>A p.I118N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV64210097; called by muse, mutect2, varscan2
- ARFGEF2 | c.2723G>A p.G908E | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV64210101; called by muse, mutect2, varscan2
- ARFGEF3 | c.2459C>T p.T820I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.449); catalogued as COSV52449231; called by muse, mutect2
- ARHGAP21 | c.871C>T p.H291Y | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.478); catalogued as COSV57601601; called by muse, mutect2, varscan2
- ARHGAP27 | c.1459C>A p.P487T (on ENST00000428638 / NM_001282290.1; = p.P146T on NM_199282.3) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV65356957, COSV65358922; called by mutect2, varscan2
- ARHGAP29 | c.3623A>C p.D1208A | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV53107623; called by muse, mutect2, varscan2
- ARHGAP29 | c.1991G>A p.G664E | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53107636; called by muse, mutect2, varscan2
- ARHGAP30 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100920257; called by muse, mutect2, varscan2
- ARHGAP44 | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52388543; called by muse, mutect2, varscan2
- ARHGAP44 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as rs762643264, COSV52388554; called by mutect2, varscan2
- ARHGEF16 | c.1322C>T p.T441I | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV65681200; called by muse, mutect2, varscan2
- ARHGEF28 | c.4843G>A p.D1615N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.157); catalogued as COSV55246396; called by muse, mutect2, varscan2
- ARHGEF40 | c.2202T>G p.D734E | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV53877960; called by muse, mutect2, varscan2
- ARID4B | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51597602; called by muse, mutect2
- ARID4B | c.1100A>G p.Q367R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV51597616; called by muse, mutect2
- ARNTL2 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779219673, COSV99667759; called by muse, mutect2, varscan2
- ARNTL2 | c.1178G>A p.G393E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53823110; called by muse, mutect2, varscan2
- ARSF | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV63838701; called by muse, mutect2, varscan2
- ARSH | c.216G>A p.G72= | Splice Region (SNP) | VAF 77/84 reads (92%) | catalogued as COSV66962461; called by muse, mutect2, varscan2
- ARSH | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 28/29 reads (97%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as rs754620451, COSV66962463; called by muse, mutect2, varscan2
- ART5 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV63363888; called by muse, mutect2, varscan2
- ASAP3 | c.2414C>T p.P805L | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.351); catalogued as rs372626373; called by muse, mutect2, varscan2
- ASXL3 | c.4984A>G p.T1662A | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV52455942; called by muse, varscan2
- ASXL3 | c.5083G>A p.A1695T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV52455952; called by muse, varscan2
- ATAD3B | c.356C>T p.S119F (on ENST00000308647; = p.S225F on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs762459652, COSV58021837; called by mutect2, varscan2
- ATP11C | c.206G>A p.R69K | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59558906, COSV59560563; called by muse, mutect2, varscan2
- ATP13A4 | c.2542G>A p.D848N | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1313425330, COSV61315707; called by muse, mutect2, varscan2
- ATP13A4 | c.1625C>T p.T542I | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as COSV55065454, COSV55073632; called by muse, mutect2, varscan2
- ATP13A5 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1340327629, COSV60865060; called by muse, mutect2, varscan2
- ATP1A2 | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 49/66 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV63401935; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1577G>A p.W526* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as COSV59472121; called by muse, mutect2, varscan2
- ATP6V0A4 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1563006614, COSV59472133; called by muse, mutect2, varscan2
- ATP9A | c.196T>A p.F66I | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV58762351; called by mutect2, varscan2
- B3GNT7 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs369358770; called by muse, mutect2, varscan2
- B4GALNT4 | c.3092G>A p.R1031K | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs764817734, COSV100327525; called by muse, varscan2
- B9D2 | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.368); catalogued as COSV54683483; called by muse, varscan2
- B9D2 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as COSV99699143; called by muse, varscan2
- BACE1 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.64); catalogued as COSV56117453; called by muse, mutect2, varscan2
- BAG2 | c.239T>G p.L80* | Nonsense Mutation (SNP) | VAF 27/58 reads (47%) | catalogued as COSV65786623; called by muse, mutect2, varscan2
- BANK1 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as COSV59837708; called by mutect2, varscan2
- BARX1 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54158650; called by muse, mutect2, varscan2
- BAZ2B | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV58595062; called by muse, mutect2, varscan2
- BBS7 | c.1336C>T p.R446W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768987725, COSV52656660; called by mutect2, varscan2
- BDKRB2 | c.776T>G p.F259C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as COSV60013394; called by muse, mutect2, varscan2
- BDKRB2 | c.1032G>T p.W344C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV60013402; called by mutect2, varscan2
- BFSP1 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as COSV64899180; called by muse, mutect2, varscan2
- BIRC6 | c.12941G>A p.R4314K | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated (0.41); PolyPhen benign (0.239); catalogued as COSV70194956; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.199T>C p.Y67H | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57278007; called by muse, mutect2, varscan2
- BMP15 | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 54/56 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53139738, COSV53140954; called by muse, mutect2, varscan2
- BMP3 | c.1016G>T p.R339I | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51081556, COSV99261835; called by mutect2, varscan2
- BNIP5 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as COSV71325262; called by muse, mutect2, varscan2
- BPIFC | c.1149C>T p.F383= | Splice Region (SNP) | VAF 32/72 reads (44%) | catalogued as rs200868839, COSV55910552; called by muse, mutect2, varscan2
- BRAP | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV59535252; called by muse, mutect2, varscan2
- BRCA1 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV58783369; called by mutect2, varscan2
- BTAF1 | c.4097G>C p.R1366T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56429278; called by muse, mutect2, varscan2
- BUB1 | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs749702538, COSV57061006; called by muse, mutect2, varscan2
- C11orf24 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); catalogued as COSV58504861; called by muse, mutect2, varscan2
- C12orf54 | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 52/81 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs1052300938, COSV58359864; called by muse, mutect2, varscan2
- C19orf57 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.076); catalogued as COSV60967034; called by muse, mutect2, varscan2
- C1QTNF9 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100129803; called by muse, mutect2, varscan2
- C1QTNF9B | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65943804; called by muse, mutect2, varscan2
- C1R | c.991G>A p.E331K (on ENST00000536053 / NM_001354346.2; = p.E317K on NM_001733.7) | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as rs772306231, COSV73293776; ClinVar: uncertain significance; called by mutect2, varscan2
- C1orf43 | c.634C>T p.P212S (on ENST00000368521 / NM_001297718.2; = p.P178S on NM_015449.4) | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.043); catalogued as COSV62965742; called by muse, mutect2, varscan2
- C20orf194 | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV52690674, COSV52700082; called by muse, mutect2, varscan2
- C20orf96 | c.668C>T p.S223F (on ENST00000360321 / NM_153269.3; = p.S222F on NM_080571.1) | Missense Mutation (SNP) | VAF 95/195 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.826); catalogued as rs199526456; called by muse, mutect2, varscan2
- C2orf16 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV101284389; called by mutect2, varscan2
- C2orf16 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as COSV101284390; called by muse, mutect2, varscan2
- C3 | c.3976G>A p.E1326K | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV55567907; called by muse, mutect2, varscan2
- C3 | c.2860C>T p.R954C | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as rs922362504, COSV55567915; called by muse, mutect2, varscan2
- C3orf18 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as rs140626565, COSV61747355; called by muse, mutect2
- C4BPA | c.680G>A p.W227* | Nonsense Mutation (SNP) | VAF 27/37 reads (73%) | catalogued as COSV65535566; called by muse, mutect2, varscan2
- C4BPA | c.1118G>A p.G373D | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); catalogued as COSV65535572; called by muse, mutect2, varscan2
- C4BPB | c.306A>T p.K102N | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.081); catalogued as COSV54690620, COSV54692072; called by mutect2, varscan2
- C4orf46 | c.88T>G p.S30A | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.031); catalogued as COSV57013977; called by muse, mutect2, varscan2
- C6 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54704266; called by muse, mutect2, varscan2
- C6orf58 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs776708642, COSV100314876; called by muse, mutect2, varscan2
- C7 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs772422101, COSV57470105; called by muse, mutect2
- C7 | c.1973C>T p.S658F | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs866073266, COSV57470115; called by muse, mutect2, varscan2
- C8A | c.19T>A p.F7I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as rs1236989252, COSV63482989; called by mutect2, varscan2
- C8orf34 | c.1550-1G>A p.X517_splice | Splice Site (SNP) | VAF 19/38 reads (50%) | catalogued as COSV61369429, COSV61377315; called by muse, mutect2, varscan2
- CAB39L | c.820T>C p.F274L | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1251772623, COSV100759557; called by muse, mutect2, varscan2
- CACNA1A | c.712C>A p.L238I | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64188605; called by muse, mutect2, varscan2
- CACNA1B | c.1902G>A p.Q634= | Splice Region (SNP) | VAF 77/122 reads (63%) | catalogued as COSV53111876; called by muse, mutect2, varscan2
- CACNA1D | c.6259G>A p.E2087K (on ENST00000350061 / NM_001128840.3; = p.E2107K on NM_000720.4) | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs762059527, COSV55436089, COSV55439012; called by muse, mutect2, varscan2
- CACNA1F | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.69); catalogued as COSV100544798, COSV59903641; called by muse, mutect2, varscan2
- CACNG3 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 24/42 reads (57%) | catalogued as COSV50063828, COSV99136896; called by muse, mutect2, varscan2
- CADM2 | c.379C>T p.P127S (on ENST00000407528 / NM_001167674.2; = p.P129S on NM_153184.4) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67355220; called by muse, mutect2, varscan2
- CADM3 | c.665C>T p.S222F (on ENST00000368125 / NM_001127173.3; = p.S256F on NM_021189.5) | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.608); catalogued as rs867065366, COSV63683495; called by muse, mutect2, varscan2
- CAGE1 | c.1658G>A p.R553K (on ENST00000512086; = p.R417K on NM_205864.3) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV57074075; called by muse, mutect2
- CALHM5 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748229444, COSV62067221; called by muse, mutect2, varscan2
- CALML5 | c.393C>G p.D131E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV66702327, COSV66702388; called by muse, mutect2
- CAMSAP3 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.826); catalogued as rs375671131; called by muse, mutect2, varscan2
- CAMTA1 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as rs756787846, COSV57879540; called by muse, varscan2
- CAMTA1 | c.3190C>T p.R1064C | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762992014, COSV100349403, COSV100351536; called by mutect2, varscan2
- CAPN13 | c.1280T>A p.F427Y | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV54427959; called by mutect2, varscan2
- CAPN15 | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766442994, COSV99562448; called by muse, mutect2, varscan2
- CAPN9 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV55230030; called by mutect2, varscan2
- CARD18 | c.215T>A p.F72Y | Missense Mutation (SNP) | VAF 68/135 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV101596040, COSV73233128; called by muse, mutect2, varscan2
- CARNS1 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1469971369, COSV57129589; called by muse, mutect2, varscan2
- CASD1 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV51970453; called by muse, mutect2, varscan2
- CASR | c.1625T>C p.F542S (on ENST00000490131; = p.F619S on NM_000388.4) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as COSV56133793; called by muse, mutect2, varscan2
- CASZ1 | c.4118G>A p.R1373Q | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs747059584, COSV59731157; called by muse, mutect2, varscan2
- CATSPERB | c.2948G>A p.W983* | Nonsense Mutation (SNP) | VAF 29/56 reads (52%) | catalogued as rs753707690, COSV56421495; called by muse, mutect2, varscan2
- CATSPERB | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as COSV56421508; called by muse, mutect2, varscan2
- CATSPERB | c.298A>G p.N100D | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV56421526; called by muse, mutect2, varscan2
- CBX2 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV99490863; called by mutect2, varscan2
- CCDC134 | c.317C>A p.S106Y | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55387436; called by muse, varscan2
- CCDC14 | c.2630C>A p.S877* (on ENST00000488653; = p.S829* on NM_022757.5) | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV59942733, COSV59946220; called by mutect2, varscan2
- CCDC141 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as COSV55368066; called by muse, mutect2, varscan2
- CCDC170 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.798); catalogued as COSV53336291; called by muse, mutect2, varscan2
- CCDC38 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60182046; called by muse, mutect2, varscan2
- CCDC47 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56721595; called by muse, mutect2, varscan2
- CCDC54 | c.763C>T p.H255Y | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); catalogued as COSV53757825; called by muse, varscan2
- CCDC65 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.391); catalogued as rs1305460586, COSV57194419; called by muse, mutect2, varscan2
- CCDC8 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.021); catalogued as rs748217595, COSV56772058; called by muse, mutect2, varscan2
- CCDC88C | c.4256A>T p.K1419I | Missense Mutation (SNP) | VAF 135/297 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58660265; called by muse, mutect2, varscan2
- CCDC91 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as COSV60338636; called by muse, mutect2, varscan2
- CCM2L | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV52948764, COSV52953622; called by muse, mutect2, varscan2
- CCNL2 | c.548T>C p.V183A | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV68766054; called by muse, mutect2, varscan2
- CCR1 | c.748C>T p.L250F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.208); catalogued as rs866089461, COSV56121572; called by muse, mutect2, varscan2
- CCR9 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV62939713; called by muse, mutect2, varscan2
- CD163L1 | c.4280-1G>A p.X1427_splice | Splice Site (SNP) | VAF 13/20 reads (65%) | catalogued as COSV58010361; called by muse, mutect2, varscan2
- CD163L1 | c.1921G>A p.G641R | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759593557, COSV58010371; called by muse, mutect2, varscan2
- CD33 | c.62T>A p.F21Y | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51799680; called by muse, mutect2, varscan2
- CD36 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs145908803; called by muse, mutect2, varscan2
- CD74 | c.707G>A p.G236D | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99153746; called by muse, mutect2, varscan2
- CD74 | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335527634, COSV99153751; called by mutect2, varscan2
- CDC25C | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as COSV60401478; called by mutect2, varscan2
- CDC25C | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.681); catalogued as COSV100086702; called by muse, mutect2, varscan2
- CDC45 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 63/134 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs906543038, COSV54243116; called by muse, mutect2, varscan2
- CDH18 | c.2369C>T p.T790I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.42); catalogued as COSV56898134; called by muse, mutect2, varscan2
- CDH2 | c.1576C>T p.R526* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as rs748735492, COSV52271435; called by mutect2, varscan2
- CDH23 | c.2852C>T p.T951I | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV54923002; called by muse, mutect2, varscan2
- CDH23 | c.3840G>A p.M1280I | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1472068649, COSV56445819; called by mutect2, varscan2
- CDH23 | c.6320G>A p.R2107Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs780094972, COSV56460135; called by muse, mutect2, varscan2
- CDH8 | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV54845337; called by mutect2, varscan2
- CDH9 | c.2244T>A p.D748E | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50250769; called by muse, mutect2, varscan2
- CDHR1 | c.2492C>T p.T831I | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.023); catalogued as COSV60559200; called by muse, mutect2, varscan2
- CDK12 | c.2830C>T p.Q944* | Nonsense Mutation (SNP) | VAF 28/52 reads (54%) | catalogued as COSV101420398, COSV70999045; called by mutect2, varscan2
- CDR1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 45/48 reads (94%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.917); catalogued as COSV65163794; called by muse, mutect2, varscan2
- CEMIP | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 91/100 reads (91%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV54987506; called by muse, mutect2, varscan2
- CEMIP2 | c.1988C>T p.S663L | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65485328; called by mutect2, varscan2
- CEMIP2 | c.1213C>T p.L405F | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV65485332; called by muse, mutect2, varscan2
- CENPE | c.2857C>T p.H953Y | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV54375438; called by mutect2, varscan2
- CENPF | c.9250C>T p.P3084S | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.542); catalogued as COSV65272330; called by muse, mutect2, varscan2
- CEP112 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); catalogued as COSV67135522; called by muse, mutect2, varscan2
- CEP128 | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV99824656; called by muse, mutect2, varscan2
- CEP350 | c.4910A>C p.N1637T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.317); catalogued as rs1045108151, COSV62598371; called by muse, mutect2, varscan2
- CEP43 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV62760341; called by muse, mutect2, varscan2
- CEP78 | c.2018C>G p.S673C (on ENST00000424347 / NM_001349840.2; = p.S674C on NM_032171.3) | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as COSV99450430; called by muse, mutect2, varscan2
- CES5A | c.1261C>T p.R421* | Nonsense Mutation (SNP) | VAF 26/31 reads (84%) | catalogued as rs757552122, COSV51863208; called by muse, mutect2, varscan2
- CFAP100 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100729351, COSV61502278; called by mutect2, varscan2
- CFAP206 | c.977T>A p.L326H | Missense Mutation (SNP) | VAF 77/154 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51532315; called by muse, mutect2, varscan2
- CFAP43 | c.4348G>A p.E1450K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV63851694; called by muse, mutect2, varscan2
- CFAP45 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0.01); catalogued as COSV63647852; called by muse, mutect2, varscan2
- CFAP47 | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99935001; called by muse, mutect2, varscan2
- CFAP47 | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99935003; called by muse, mutect2, varscan2
- CFAP53 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV68351208; called by muse, mutect2, varscan2
- CFAP57 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 61/81 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63016633; called by muse, mutect2, varscan2
- CFAP70 | c.2935C>T p.H979Y | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.77); PolyPhen benign (0.039); catalogued as COSV60280638; called by muse, mutect2, varscan2
- CGN | c.2306G>A p.R769Q | Missense Mutation (SNP) | VAF 55/79 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1287581425, COSV54974773; called by mutect2, varscan2
- CHCHD2 | c.48C>T p.A16= | Splice Region (SNP) | VAF 39/45 reads (87%) | catalogued as rs771253445, COSV101271043; called by mutect2, varscan2
- CHCHD2 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT tolerated (0.12); PolyPhen benign (0.439); catalogued as COSV101271044; called by muse, mutect2, varscan2
- CHD1 | c.4312C>T p.L1438F | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52336295; called by muse, mutect2, varscan2
- CHD4 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as CM161421, COSV100538016; called by mutect2, varscan2
- CHD6 | c.6427C>T p.P2143S | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV64687925; called by muse, mutect2, varscan2
- CHGA | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50893762, COSV50900785; called by muse, mutect2, varscan2
- CHIT1 | c.995T>A p.V332E | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55144987; called by muse, mutect2, varscan2
- CHL1 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV56585273; called by mutect2, varscan2
- CHRM3 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55078511, COSV55085928; called by muse, mutect2, varscan2
- CHRNA9 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 198/313 reads (63%) | SIFT tolerated (0.23); PolyPhen benign (0.369); catalogued as rs201389718, COSV59573377; called by muse, mutect2, varscan2
- CHRNB3 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs769973790, COSV51492877; called by muse, mutect2, varscan2
- CIAPIN1 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 43/46 reads (93%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV101275886; called by muse, mutect2, varscan2
- CIAPIN1 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 45/48 reads (94%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV101275887; called by muse, mutect2, varscan2
- CIC | c.4150C>T p.R1384W | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355435851, COSV99359561; called by mutect2, varscan2
- CIT | c.1583T>G p.V528G | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.388); catalogued as COSV55858811; called by muse, mutect2, varscan2
- CLEC14A | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV60561512; called by muse, mutect2, varscan2
- CLEC4M | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 26/60 reads (43%) | catalogued as COSV50216683; called by mutect2, varscan2
- CLGN | c.1732A>C p.K578Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.131); catalogued as rs1374247112, COSV57773038; called by muse, mutect2, varscan2
- CLIC5 | c.677C>A p.A226D (on ENST00000185206 / NM_001370649.1; = p.A67D on NM_016929.5) | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51761399, COSV99484439; called by mutect2, varscan2
- CLIC5 | c.676G>T p.A226S (on ENST00000185206 / NM_001370649.1; = p.A67S on NM_016929.5) | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV99484447; called by mutect2, varscan2
- CLSTN2 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 73/113 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV71717615; called by muse, mutect2, varscan2
- CLVS1 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as COSV57969933; called by muse, mutect2, varscan2
- CLYBL | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 32/78 reads (41%) | catalogued as rs747308343, COSV59216284; called by mutect2, varscan2
- CMKLR1 | c.32C>T p.S11F (on ENST00000312143 / NM_001142344.2; = p.S9F on NM_004072.3) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV56435946; called by muse, mutect2, varscan2
- CMTM7 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV58549732; called by mutect2, varscan2
- CMYA5 | c.4382C>T p.S1461L | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV71404011; called by muse, mutect2, varscan2
- CMYA5 | c.11293G>A p.E3765K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV71404012; called by muse, mutect2, varscan2
- CNBD2 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs534729039, COSV62586255; called by mutect2, varscan2
- CNGA2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as rs764689669, COSV61702940; called by muse, mutect2, varscan2
- CNGA4 | c.546G>A p.W182* | Nonsense Mutation (SNP) | VAF 36/62 reads (58%) | catalogued as COSV66004894; called by muse, mutect2
- CNGA4 | c.548A>C p.N183T | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV66004902; called by muse, mutect2
- CNGB3 | c.1225G>A p.G409S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781293627, COSV60683883; called by muse, mutect2, varscan2
- CNNM2 | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as rs1253168085, COSV63996660; called by muse, mutect2, varscan2
- CNTN4 | c.223T>A p.F75I | Missense Mutation (SNP) | VAF 67/102 reads (66%) | SIFT tolerated (0.24); PolyPhen benign (0.061); catalogued as COSV68560948; called by mutect2, varscan2
- CNTN5 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.274); catalogued as rs867263470, COSV54275457; called by muse, mutect2, varscan2
- CNTN5 | c.2167C>T p.P723S | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54275498; called by muse, mutect2, varscan2
- CNTNAP4 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.776); catalogued as COSV56662156; called by muse, mutect2, varscan2
- CNTNAP5 | c.1916T>A p.L639Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.721); catalogued as COSV70470062; called by mutect2, varscan2
- CNTRL | c.3709C>T p.P1237S | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV53042563; called by muse, mutect2, varscan2
- COBL | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 28/30 reads (93%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs202232985, COSV54336910; called by mutect2, varscan2
- COL13A1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100637466; called by muse, mutect2, varscan2
- COL13A1 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100637467; called by mutect2, varscan2
- COL25A1 | c.1155G>A p.G385= | Splice Region (SNP) | VAF 84/249 reads (34%) | catalogued as COSV67645795; called by muse, mutect2, varscan2
- COL2A1 | c.3583G>A p.E1195K | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1186663188, COSV61527447; called by mutect2, varscan2
- COL4A1 | c.2296C>T p.P766S | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65420526; called by muse, mutect2, varscan2
- COL4A1 | c.2027G>T p.G676V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65420531; called by muse, mutect2, varscan2
- COL4A1 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.976); catalogued as COSV65420535; called by muse, mutect2, varscan2
- COL4A3 | c.1998T>A p.H666Q | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV101170332, COSV67412326; called by muse, mutect2, varscan2
- COL5A1 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.169); catalogued as COSV65664508; called by muse, mutect2, varscan2
- COL5A3 | c.3527C>T p.P1176L | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV53405271, COSV53420560; called by muse, mutect2, varscan2
- COL6A2 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs776748046, COSV100153618, COSV55997854; called by muse, mutect2, varscan2
- COL9A1 | c.2651G>A p.G884E | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57877921; called by muse, mutect2, varscan2
- COPE | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as rs1002259641, COSV53229270; called by muse, varscan2
- COPG2 | c.2354C>T p.T785I | Missense Mutation (SNP) | VAF 128/319 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV56227395; called by muse, mutect2, varscan2
- CORO1A | c.327G>A p.W109* | Nonsense Mutation (SNP) | VAF 25/48 reads (52%) | catalogued as COSV54630278, COSV99531949; called by muse, mutect2, varscan2
- COX4I2 | c.21G>A p.W7* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV65781631; called by muse, mutect2, varscan2
- CPA1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV50568068; called by muse, mutect2
- CPE | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 120/430 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.024); catalogued as COSV68579059; called by muse, mutect2, varscan2
- CPM | c.1143A>T p.K381N | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV58031528; called by muse, mutect2, varscan2
- CRABP1 | c.162G>C p.K54N | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV55115270; called by muse, varscan2
- CRAMP1 | c.3581C>T p.P1194L | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs947619230, COSV51959156; called by muse, mutect2, varscan2
- CREB3L1 | c.1372C>T p.P458S | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as COSV55830211; called by muse, mutect2
- CREB3L3 | c.379C>T p.H127Y | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.142); catalogued as COSV50172203; called by mutect2, varscan2
- CREBL2 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV57428386; called by mutect2, varscan2
- CRNKL1 | c.2318G>A p.R773K | Missense Mutation (SNP) | VAF 71/138 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1485308753, COSV58547954; called by muse, mutect2, varscan2
- CRTC3 | c.1529G>A p.G510D | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV51593633; called by muse, mutect2, varscan2
- CRYBB1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV53232279; called by muse, mutect2, varscan2
- CRYBG1 | c.2305G>A p.G769R | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.093); catalogued as COSV64810299; called by muse, mutect2, varscan2
- CSDE1 | c.1189C>T p.P397S (on ENST00000358528 / NM_001007553.3; = p.P366S on NM_007158.6) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV54736501; called by muse, mutect2, varscan2
- CSHL1 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 67/130 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV51987081; called by muse, mutect2, varscan2
- CSMD2 | c.6008G>A p.G2003D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs142457038, COSV53874507; called by muse, mutect2, varscan2
- CSMD2 | c.4507G>A p.D1503N | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs199793319, COSV53874530; called by muse, varscan2
- CSMD3 | c.10108C>T p.Q3370* (on ENST00000297405 / NM_001363185.1; = p.Q3201* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 24/80 reads (30%) | catalogued as COSV52091170, COSV52119604; called by mutect2, varscan2
- CSMD3 | c.9104G>C p.C3035S (on ENST00000297405 / NM_001363185.1; = p.C2866S on NM_052900.3) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV52091190; called by muse, mutect2, varscan2
- CSMD3 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.917); catalogued as COSV52091224, COSV99821814; called by muse, mutect2, varscan2
- CSNK1G3 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62053171; called by muse, mutect2, varscan2
- CSPG5 | c.1400C>T p.S467F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV99273801; called by muse, varscan2
- CSTA | c.45A>C p.E15D | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV52611616; called by muse, mutect2, varscan2
- CTAGE1 | c.1510C>T p.L504F | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV66942790; called by muse, mutect2, varscan2
- CTBS | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 88/126 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55361022, COSV55361101; called by muse, mutect2, varscan2
- CTLA4 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs1052219132, COSV55591654; called by muse, mutect2, varscan2
- CTNNA3 | c.2501G>A p.R834Q | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs373081692, COSV65520863; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA3 | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.8); catalogued as COSV65548443; called by mutect2, varscan2
- CUX1 | c.1403A>C p.K468T (on ENST00000437600 / NM_181500.4; = p.K470T on NM_001913.5) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.085); catalogued as COSV52921914; called by muse, mutect2, varscan2
- CWH43 | c.1652A>G p.N551S | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV56935478; called by muse, mutect2, varscan2
- CYP2C19 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 44/98 reads (45%) | catalogued as COSV64906629; called by mutect2, varscan2
- CYP2C8 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.112); catalogued as rs868290348, COSV64875902; called by muse, mutect2, varscan2
- CYP3A4 | c.433-2A>C p.X145_splice | Splice Site (SNP) | VAF 35/72 reads (49%) | catalogued as COSV60500854; called by muse, mutect2, varscan2
- CYP4A22 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as rs780190981, COSV53737797; called by muse, mutect2, varscan2
- CYP4B1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 42/52 reads (81%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV54720921; called by muse, mutect2, varscan2
- CYP4B1 | c.621G>A p.R207= | Splice Region (SNP) | VAF 22/141 reads (16%) | catalogued as COSV54720935; called by muse, mutect2, varscan2
- CYP4F8 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs1272486877, COSV57852965; called by muse, mutect2, varscan2
- CYP4X1 | c.1291T>C p.F431L | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761311128, COSV64149546; called by muse, mutect2, varscan2
- CYP4Z1 | c.266T>A p.M89K | Missense Mutation (SNP) | VAF 82/116 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV61963625; called by muse, varscan2
- CYP7B1 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59581554; called by muse, mutect2, varscan2
- CYTH2 | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV57308598; called by muse, mutect2, varscan2
- CZIB | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53758567, COSV99598296; called by muse, mutect2, varscan2
- DAB2IP | c.1528C>T p.P510S (on ENST00000408936; = p.P482S on NM_032552.3) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.741); catalogued as rs1244760913, COSV99405416; called by muse, mutect2, varscan2
- DAB2IP | c.1529C>T p.P510L (on ENST00000408936; = p.P482L on NM_032552.3) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs779618321, COSV52270886; called by mutect2, varscan2
- DAB2IP | c.2116G>T p.E706* (on ENST00000408936; = p.E678* on NM_032552.3) | Nonsense Mutation (SNP) | VAF 70/116 reads (60%) | catalogued as COSV52253944, COSV99406182; called by muse, mutect2, varscan2
- DAB2IP | c.2296G>A p.G766S (on ENST00000408936; = p.G738S on NM_032552.3) | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.93); PolyPhen benign (0.009); catalogued as COSV52253958; called by muse, mutect2, varscan2
- DAP3 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs751431768, COSV58018995; called by muse, mutect2, varscan2
- DAZAP1 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.857); catalogued as COSV51830779; called by muse, mutect2, varscan2
- DCC | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59081081; called by muse, mutect2, varscan2
- DCC | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59081090; called by muse, mutect2, varscan2
- DCC | c.2909C>T p.P970L | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59081290; called by muse, mutect2, varscan2
- DCDC1 | c.5215A>G p.T1739A (on ENST00000597505 / NM_001367979.1; = p.T846A on NM_020869.3) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as rs762815244, COSV57997215; called by muse, mutect2, varscan2
- DCLK2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV56198611; called by mutect2, varscan2
- DCLK3 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated (0.36); PolyPhen benign (0.166); catalogued as COSV69362113; called by mutect2, varscan2
- DCN | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV50005974; called by muse, varscan2
- DCST1 | c.747C>T p.S249= | Splice Region (SNP) | VAF 12/75 reads (16%) | catalogued as rs764451537, COSV55056127, COSV99793136; called by muse, mutect2, varscan2
- DDC | c.56A>G p.N19S | Missense Mutation (SNP) | VAF 70/77 reads (91%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV63563381; called by muse, varscan2
- DDI1 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV56367448; called by muse, mutect2, varscan2
- DDX10 | c.187-1G>A p.X63_splice | Splice Site (SNP) | VAF 11/26 reads (42%) | catalogued as rs1176112442, COSV59430979; called by muse, mutect2, varscan2
- DDX23 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.704); catalogued as COSV100339808; called by muse, mutect2, varscan2
- DDX25 | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746583084, COSV54988359; called by muse, mutect2, varscan2
- DDX39A | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV54390327; called by muse, mutect2, varscan2
- DDX4 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV61753145; called by muse, mutect2, varscan2
- DDX42 | c.2704C>T p.P902S | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.005); catalogued as rs773939808, COSV63789166; called by muse, mutect2, varscan2
- DDX60 | c.3197A>T p.K1066M | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV67094882; called by mutect2, varscan2
- DEFB125 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV66703010; called by muse, mutect2, varscan2
- DENND4C | c.1488-1G>A p.X496_splice | Splice Site (SNP) | VAF 4/21 reads (19%) | catalogued as COSV66821356; called by muse, mutect2
- DGKG | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV53961068; called by muse, mutect2, varscan2
- DGKK | c.3784G>A p.D1262N | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.516); catalogued as COSV65706125; called by mutect2, varscan2
- DHX35 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs1358208746, COSV52667083; called by muse, mutect2, varscan2
- DIAPH3 | c.3254C>T p.P1085L (on ENST00000400324 / NM_001042517.2; = p.P822L on NM_030932.3) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV57365221, COSV99933505; called by mutect2, varscan2
- DIAPH3 | c.3253C>T p.P1085S (on ENST00000400324 / NM_001042517.2; = p.P822S on NM_030932.3) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV99933506; called by muse, mutect2, varscan2
- DIDO1 | c.4787C>T p.S1596F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.053); catalogued as COSV56612721; called by muse, mutect2, varscan2
- DIP2B | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56578124; called by muse, mutect2, varscan2
- DISP3 | c.3820G>A p.A1274T | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs888132857, COSV53819355; called by mutect2, varscan2
- DKK4 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99612909; called by muse, mutect2, varscan2
- DKK4 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1199127304, COSV99612911; called by muse, mutect2, varscan2
- DLC1 | c.3981C>G p.D1327E (on ENST00000276297 / NM_001348081.2; = p.D890E on NM_006094.5) | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as COSV52288447; called by muse, mutect2, varscan2
- DLGAP1 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.77); PolyPhen benign (0.281); catalogued as rs867594006, COSV59780392; called by muse, mutect2, varscan2
- DLGAP1 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as rs779305058, COSV59780431; called by mutect2, varscan2
- DMBT1 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 148/329 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); catalogued as COSV57532750, COSV57535112; called by muse, varscan2
- DMBT1 | c.6848C>T p.S2283F (on ENST00000338354 / NM_001377530.1; = p.S1526F on NM_004406.3) | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.242); catalogued as COSV57532788, COSV57539968; called by muse, mutect2, varscan2
- DMKN | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs746914699, COSV60084177; called by muse, mutect2, varscan2
- DMRT1 | c.925A>C p.T309P | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV101206653; called by muse, mutect2, varscan2
- DNAH10 | c.7943C>T p.S2648L (on ENST00000409039; = p.S2587L on NM_207437.3) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751315749, COSV68987215; called by muse, mutect2, varscan2
- DNAH10 | c.10192G>A p.D3398N (on ENST00000409039; = p.D3337N on NM_207437.3) | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs780437888, COSV68987221; called by mutect2, varscan2
- DNAH12 | c.800T>C p.V267A | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV60855296; called by muse, mutect2, varscan2
- DNAH12 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as rs1249658411, COSV60855321; called by muse, mutect2, varscan2
- DNAH3 | c.11492G>A p.G3831E | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs201273521, COSV54500970; called by muse, mutect2, varscan2
- DNAH3 | c.9943G>A p.E3315K | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs1376216497, COSV54500997, COSV54551376; called by muse, mutect2, varscan2
- DNAH3 | c.7409G>A p.R2470Q | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs765298123, COSV54501013; called by muse, mutect2, varscan2
- DNAH3 | c.5917A>T p.K1973* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV54501031; called by muse, mutect2, varscan2
- DNAH3 | c.4933G>A p.D1645N | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54501052; called by muse, mutect2, varscan2
- DNAH5 | c.12735G>A p.M4245I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54201432; called by muse, mutect2, varscan2
- DNAH5 | c.11811G>A p.W3937* | Nonsense Mutation (SNP) | VAF 32/70 reads (46%) | catalogued as COSV54201354; called by muse, mutect2, varscan2
- DNAH5 | c.7839G>A p.M2613I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1486813109, COSV54201446; called by mutect2, varscan2
- DNAH5 | c.5320G>A p.E1774K | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.026); catalogued as COSV54201456; called by mutect2, varscan2
- DNAH7 | c.8621A>G p.E2874G | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.388); catalogued as COSV56750107; called by muse, mutect2, varscan2
- DNAH7 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.058); catalogued as COSV56750119; called by muse, mutect2, varscan2
- DNAH8 | c.10626G>A p.V3542= | Splice Region (SNP) | VAF 26/140 reads (19%) | catalogued as COSV59421572; called by mutect2, varscan2
- DNAH8 | c.12191G>A p.R4064Q | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327466194, COSV59421605; called by muse, mutect2, varscan2
- DNAH8 | c.12301G>A p.G4101S | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1427875858, COSV59421626, COSV59480772; called by muse, mutect2, varscan2
- DNAH9 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52331766; called by muse, mutect2, varscan2
- DNM1L | c.1735G>A p.D579N (on ENST00000549701 / NM_012062.5; = p.D542N on NM_005690.4) | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV56771852; called by muse, mutect2, varscan2
- DNMT1 | c.3526G>A p.A1176T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV61576216; called by muse, mutect2, varscan2
- DNMT3L | c.328A>T p.N110Y | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV54263099; called by mutect2, varscan2
- DOCK2 | c.2360C>T p.T787I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.154); catalogued as COSV56939395; called by muse, mutect2, varscan2
- DOCK3 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.248); catalogued as rs368241903; called by mutect2, varscan2
- DOCK6 | c.1535C>T p.S512F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs759348718, COSV99370956; called by muse, varscan2
- DPYD | c.2004T>A p.N668K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64589556; called by muse, mutect2, varscan2
- DRC3 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.096); catalogued as COSV100572810, COSV58261383; called by mutect2, varscan2
- DRD2 | c.1205A>G p.N402S | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.065); catalogued as COSV60753703; called by muse, mutect2, varscan2
- DRD3 | c.317T>G p.F106C | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55678292; called by muse, mutect2, varscan2
- DSC3 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV64571434; called by muse, mutect2, varscan2
- DSCAM | c.6002G>A p.G2001E | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as COSV68019987; called by muse, mutect2, varscan2
- DSCAM | c.5638G>A p.D1880N | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV68019988; called by muse, mutect2, varscan2
- DSCAML1 | c.1237G>A p.E413K (on ENST00000321322; = p.E353K on NM_020693.4) | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.341); catalogued as COSV100355821, COSV58398914; called by muse, mutect2, varscan2
- DSE | c.1130G>A p.S377N | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.234); catalogued as COSV59061411; called by muse, varscan2
- DSE | c.1317G>A p.W439* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | catalogued as COSV59061427; called by muse, mutect2, varscan2
- DSG1 | c.3020G>A p.G1007E | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.563); catalogued as COSV57132936, COSV57137702; called by muse, mutect2, varscan2
- DSP | c.1140G>A p.Q380= | Splice Region (SNP) | VAF 14/58 reads (24%) | catalogued as COSV65790776; called by muse, mutect2, varscan2
- DSP | c.6059G>A p.G2020E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV65790785; called by muse, mutect2, varscan2
- DST | c.22211C>T p.S7404L (on ENST00000361203 / NM_001374722.1; = p.S5114L on NM_015548.5) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759656642, COSV54995134; called by mutect2, varscan2
- DYNC1H1 | c.7214G>T p.G2405V | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100794860; called by mutect2, varscan2
- DYNC2H1 | c.7315C>A p.Q2439K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as COSV62085277; called by muse, mutect2, varscan2
- DZIP1 | c.1363G>A p.G455R (on ENST00000347108; = p.V455M on NM_014934.5) | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs762590555, COSV61263599; called by muse, varscan2
- DZIP1L | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 104/175 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs188293055; called by muse, mutect2, varscan2
- EDRF1 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61762247; called by muse, mutect2, varscan2
- EGFL8 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 125/209 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV61246898; called by muse, mutect2, varscan2
- EGFR | c.2209A>G p.K737E | Missense Mutation (SNP) | VAF 41/43 reads (95%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as COSV51765811; called by muse, mutect2, varscan2
- EGR4 | c.1174C>T p.P392S (on ENST00000545030; = p.P289S on NM_001965.4) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1465664493, COSV101474246; called by muse, varscan2
- EHD2 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as rs940509437, COSV54406490; called by muse, mutect2, varscan2
- EHD2 | c.504C>T p.G168= | Splice Region (SNP) | VAF 15/29 reads (52%) | catalogued as COSV54406500; called by muse, mutect2, varscan2
- ELP2 | c.139-1G>A p.X47_splice | Splice Site (SNP) | VAF 14/28 reads (50%) | catalogued as COSV52367595, COSV99036020; called by muse, mutect2
- ENGASE | c.2018C>T p.S673F | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.364); catalogued as COSV56133737; called by muse, varscan2
- ENGASE | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs200719249; called by muse, varscan2
- ENO1 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.253); catalogued as COSV99318807; called by muse, mutect2, varscan2
- EPHA2 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV100626107; called by muse, mutect2, varscan2
- EPHA4 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 36/58 reads (62%) | catalogued as rs867613646, COSV56025551; called by mutect2, varscan2
- EPHA6 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 108/164 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750297483, COSV67556787; called by muse, mutect2, varscan2
- EPHA6 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 78/128 reads (61%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.672); catalogued as COSV67556794; called by muse, mutect2, varscan2
- EPS8L1 | c.1253C>T p.P418L (on ENST00000201647 / NM_133180.3; = p.P291L on NM_017729.3) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.444); catalogued as COSV52379798; called by muse, mutect2, varscan2
- EPS8L3 | c.46T>C p.Y16H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs369095233; called by muse, mutect2, varscan2
- ERBB4 | c.2719+1G>A p.X907_splice | Splice Site (SNP) | VAF 12/59 reads (20%) | catalogued as COSV61458561; called by muse, mutect2, varscan2
- ERC2 | c.612G>A p.M204I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV55597421; called by mutect2, varscan2
- EREG | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 24/34 reads (71%) | catalogued as rs376236920, COSV55262382; called by muse, mutect2, varscan2
- ERG | c.695G>A p.G232E (on ENST00000398919 / NM_001243428.1; = p.G225E on NM_182918.4) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV55726447; called by muse, mutect2, varscan2
- ERICH3 | c.927T>G p.D309E | Missense Mutation (SNP) | VAF 45/57 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV58598310; called by muse, mutect2, varscan2
- ERICH6 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.731); catalogued as COSV55798588; called by mutect2, varscan2
- ERVFRD-1 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 101/169 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.184); catalogued as rs752953220, COSV65368500; called by muse, mutect2, varscan2
- ESF1 | c.2264T>G p.V755G | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52518678; called by muse, mutect2
- ESF1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs186231642, COSV52518687, COSV52523168; called by mutect2, varscan2
- ESS2 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52815975; called by muse, mutect2, varscan2
- ETS1 | c.1196A>T p.K399I | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60091412; called by mutect2, varscan2
- EVPL | c.6068C>T p.S2023F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV56906669; called by muse, mutect2
- EVX2 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57962291; called by mutect2, varscan2
- EXOC3L2 | c.1550C>T p.T517I | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.55); catalogued as COSV52971820; called by muse, mutect2, varscan2
- EXOC7 | c.2106G>A p.K702= (on ENST00000335146 / NM_001145297.4; = p.K620= on NM_015219.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 15/34 reads (44%) | catalogued as COSV100135255; called by muse, mutect2, varscan2
- EXOC7 | c.2106-1G>A p.X702_splice (on ENST00000335146 / NM_001145297.4; = p.X620_splice on NM_015219.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 15/35 reads (43%) | catalogued as COSV100135256; called by muse, mutect2, varscan2
- F7 | c.317-1G>A p.X106_splice | Splice Site (SNP) | VAF 44/88 reads (50%) | catalogued as CS001423, CS099491, COSV60644788; called by muse, mutect2, varscan2
- FAHD1 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs769628893, COSV66899430; called by muse, mutect2, varscan2
- FAM135B | c.3859G>A p.D1287N | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52702219, COSV99417199; called by mutect2, varscan2
- FAM135B | c.1756G>A p.G586R | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV52702259; called by muse, mutect2, varscan2
- FAM135B | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752489635, COSV50521991, COSV50523965; called by muse, mutect2, varscan2
- FAM155A | c.685T>C p.Y229H | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs758623794, COSV65547323; called by muse, mutect2, varscan2
- FAM193B | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV61557317; called by muse, mutect2, varscan2
- FAM193B | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as COSV61557323; called by mutect2, varscan2
- FAM209B | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as rs1445616916, COSV64914975; called by muse, mutect2, varscan2
- FAM47A | c.2138C>T p.P713L | Missense Mutation (SNP) | VAF 40/42 reads (95%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV60496925; called by muse, mutect2, varscan2
- FAM47A | c.2137C>T p.P713S | Missense Mutation (SNP) | VAF 40/42 reads (95%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV100649881, COSV60494047; called by muse, mutect2, varscan2
- FAM47A | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 49/49 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759842755, COSV60493645; called by muse, mutect2, varscan2
- FAM47C | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV63723407; called by muse, mutect2, varscan2
- FAM71A | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54234471; called by muse, mutect2, varscan2
- FAM71A | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs754560739, COSV54234481; called by muse, mutect2, varscan2
- FAM71B | c.1598A>G p.K533R | Missense Mutation (SNP) | VAF 305/707 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57227323; called by muse, mutect2, varscan2
- FAM71D | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as rs147934887, COSV61296157; called by muse, mutect2
- FAM71F1 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.365); catalogued as COSV59372688; called by muse, mutect2, varscan2
- FAM83E | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.736); catalogued as COSV99572214; called by muse, varscan2
- FAM83G | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as COSV58754983; called by muse, mutect2, varscan2
- FAM98B | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 43/43 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV59842543; called by muse, mutect2, varscan2
- FANCI | c.3566G>A p.G1189E (on ENST00000310775 / NM_001376911.1; = p.G1129E on NM_018193.3) | Missense Mutation (SNP) | VAF 31/31 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.117); catalogued as COSV55522032; called by muse, mutect2, varscan2
- FASLG | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60679616; called by muse, mutect2, varscan2
- FASN | c.2365C>T p.H789Y | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1384884525, COSV60749793; called by mutect2, varscan2
- FAT3 | c.12064C>T p.P4022S | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.849); catalogued as COSV53071024, COSV53149595; called by muse, mutect2, varscan2
- FAT4 | c.4300C>T p.P1434S | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.995); catalogued as COSV67880651; called by muse, mutect2, varscan2
- FAT4 | c.11368G>A p.E3790K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as rs776516773, COSV58669787; called by muse, mutect2, varscan2
- FAT4 | c.12112A>T p.R4038* | Nonsense Mutation (SNP) | VAF 28/84 reads (33%) | catalogued as COSV58669800; called by muse, mutect2, varscan2
- FBLIM1 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV60028331; called by muse, varscan2
- FBLN2 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as rs771592443, COSV55480393; called by mutect2, varscan2
- FBN2 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52535424; called by mutect2, varscan2
- FBXO11 | c.2450A>T p.N817I (on ENST00000403359 / NM_001190274.2; = p.N733I on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52273435; called by muse, mutect2, varscan2
- FBXW10 | c.3127G>A p.A1043T | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV57059076; called by muse, mutect2, varscan2
- FCGR2B | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as rs267598138, COSV52680477; called by muse, mutect2, varscan2
- FCRL5 | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 42/60 reads (70%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100708668; called by muse, mutect2, varscan2
- FCRL5 | c.1843G>A p.G615R | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as rs760631956, COSV62516564; called by muse, mutect2, varscan2
- FCRLA | c.437G>A p.G146E (on ENST00000367959; = p.G123E on NM_032738.4) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV52684075; called by muse, mutect2, varscan2
- FCRLB | c.62A>G p.E21G | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV61059199; called by muse, varscan2
- FGFR2 | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60638386, COSV60639189; called by muse, mutect2, varscan2
- FGGY | c.1384C>A p.P462T | Missense Mutation (SNP) | VAF 108/154 reads (70%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV58025175; called by muse, mutect2, varscan2
- FHDC1 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 77/263 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753783811, COSV52597165; called by muse, mutect2, varscan2
- FHOD3 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.075); catalogued as COSV57163076; called by mutect2, varscan2
- FILIP1 | c.3017C>T p.P1006L | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52722163; called by muse, mutect2, varscan2
- FILIP1 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV52722183; called by muse, mutect2, varscan2
- FIZ1 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV99684569; called by muse, mutect2, varscan2
- FKBPL | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 160/520 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV64322278; called by muse, mutect2, varscan2
- FLG | c.4577G>A p.G1526E | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.264); catalogued as rs776816341, COSV64235652; called by muse, mutect2, varscan2
- FLG2 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV66166301; called by muse, mutect2, varscan2
- FLI1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs574828243, COSV55642199; called by muse, mutect2
- FLNB | c.7648C>T p.H2550Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.029); catalogued as COSV99913168; called by muse, varscan2
- FMN2 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs775540805, COSV60414993, COSV60461217; called by muse, mutect2, varscan2
- FMN2 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100145014; called by muse, mutect2, varscan2
- FMN2 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60431117; called by muse, mutect2, varscan2
- FMN2 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV60415000; called by muse, mutect2, varscan2
- FMNL3 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs753891247, COSV53305581; called by muse, mutect2, varscan2
- FNBP1 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1175557567, COSV63085035; called by muse, mutect2, varscan2
- FOXN1 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV56880278; called by muse, varscan2
- FOXN1 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV56880293; called by muse, varscan2
- FOXO3 | c.1347G>T p.Q449H | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV59626093; called by muse, mutect2, varscan2
- FRAS1 | c.5566C>T p.H1856Y | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV53586140; called by muse, mutect2, varscan2
- FRAS1 | c.8752G>A p.V2918M | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53586172; called by muse, mutect2, varscan2
- FREM1 | c.4792G>A p.G1598R | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1293171999, COSV101085202, COSV66517028; called by muse, mutect2, varscan2
- FREM2 | c.3604G>A p.E1202K | Missense Mutation (SNP) | VAF 79/161 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54826775; called by muse, mutect2, varscan2
- FREM2 | c.5293C>T p.R1765C | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs770772406, COSV54826790; called by mutect2, varscan2
- FRG2B | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV71042419; called by muse, mutect2, varscan2
- FRMPD2 | c.2839G>A p.E947K | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as rs868961783, COSV59714650; called by mutect2, varscan2
- FRMPD2 | c.1275C>A p.F425L | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs768872781, COSV100564190, COSV59714658; called by muse, mutect2, varscan2
- FUBP3 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100156092; called by mutect2, varscan2
- FUT9 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV56141495; called by muse, mutect2, varscan2
- FXR1 | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV59760702; called by muse, mutect2, varscan2
- FZR1 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV58050039; called by muse, mutect2, varscan2
- GABRA1 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50098457; called by muse, mutect2, varscan2
- GABRA1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.124); catalogued as COSV50098462, COSV50111407; called by muse, mutect2, varscan2
- GABRB1 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV54969284; called by muse, mutect2, varscan2
- GABRG1 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.232); catalogued as COSV54949342, COSV99040238; called by muse, mutect2, varscan2
- GABRQ | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 89/93 reads (96%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs782766146, COSV64780696; called by muse, mutect2, varscan2
- GALNS | c.1327C>T p.H443Y | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1349775646, COSV51935442; called by muse, mutect2, varscan2
- GALNT13 | c.67T>A p.F23I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV67208634; called by mutect2, varscan2
- GALNT16 | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.098); catalogued as COSV61884387; called by muse, mutect2, varscan2
- GALNT17 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61145698; called by muse, mutect2, varscan2
- GALR1 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.225); catalogued as rs754513356, COSV55316845; called by muse, mutect2, varscan2
- GATAD2A | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs749436124, COSV53065951; called by mutect2, varscan2
- GBA3 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 34/132 reads (26%) | catalogued as rs201515557, COSV72437804, COSV72438258; called by muse, varscan2
- GCAT | c.425T>C p.F142S | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1002386930, COSV50648606; called by muse, mutect2
- GDA | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1210696523, COSV52989970; called by muse, mutect2, varscan2
- GDE1 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs200327001, COSV62059097; called by muse, mutect2, varscan2
- GDPD4 | c.617C>A p.A206E | Missense Mutation (SNP) | VAF 89/185 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60016757; called by muse, mutect2, varscan2
- GGA2 | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs867070969, COSV100564691; called by muse, mutect2, varscan2
- GGA2 | c.1222G>A p.G408S | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100564692; called by mutect2, varscan2
- GGT6 | c.886G>A p.E296K (on ENST00000574154 / NM_001122890.3; = p.E264K on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV54592739; called by muse, mutect2, varscan2
- GIMAP8 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); catalogued as rs756123094, COSV56229483, COSV56232886; called by mutect2, varscan2
- GIMAP8 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56229490; called by muse, mutect2, varscan2
- GIMAP8 | c.1849C>T p.L617F | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56229499; called by muse, mutect2, varscan2
- GIP | c.84C>T p.F28= | Splice Region (SNP) | VAF 40/84 reads (48%) | catalogued as COSV62466800; called by mutect2, varscan2
- GIPC1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV52874325; called by muse, mutect2, varscan2
- GLI2 | c.3863C>T p.P1288L (on ENST00000361492 / NM_001374353.1; = p.P1305L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.176); catalogued as COSV58033891; called by muse, mutect2
- GLIS1 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs200512169, COSV56542937; called by muse, mutect2, varscan2
- GLIS3 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV60923301, COSV60933476; called by muse, mutect2, varscan2
- GLP2R | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 76/146 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52321543; called by muse, mutect2, varscan2
- GLYATL2 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV54848830; called by muse, mutect2, varscan2
- GMIP | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs144451705; called by mutect2, varscan2
- GNAZ | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV50736827; called by muse, mutect2, varscan2
- GNPTAB | c.2111C>T p.P704L | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV54776379, COSV54777875; called by muse, mutect2, varscan2
- GOT2 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV55330527; called by muse, mutect2, varscan2
- GP5 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV55461073; called by muse, mutect2, varscan2
- GPC6 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.665); catalogued as COSV65519495; called by muse, mutect2, varscan2
- GPR152 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100351519; called by muse, mutect2, varscan2
- GPR158 | c.3557G>T p.R1186I | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV66264474; called by mutect2, varscan2
- GPR22 | c.921A>C p.R307S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV51741771; called by muse, mutect2, varscan2
- GPR61 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68177280; called by muse, mutect2, varscan2
- GPR63 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV57739374; called by muse, mutect2, varscan2
- GPRC6A | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs577170488, COSV59951296; called by mutect2, varscan2
- GRAMD1A | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as COSV58765622; called by muse, mutect2, varscan2
- GRAP2 | c.103T>C p.F35L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV59993701; called by muse, mutect2, varscan2
- GREM2 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as rs754096135, COSV58946029, COSV58958438; called by muse, mutect2, varscan2
- GRIA4 | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56879536, COSV56898445; called by muse, mutect2, varscan2
- GRIK1 | c.2297A>G p.N766S | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375794566, COSV58709453; called by muse, mutect2, varscan2
- GRIN2A | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866473134, COSV58018267; called by mutect2, varscan2
- GRIP1 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs200211966, COSV54014381; called by mutect2, varscan2
- GRK7 | c.1319G>A p.G440E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99379865; called by muse, mutect2, varscan2
- GRM6 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.16); PolyPhen benign (0.103); catalogued as COSV51432236; called by muse, mutect2, varscan2
- GRM6 | c.1319T>C p.M440T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV51432277; called by muse, mutect2, varscan2
- GSDMA | c.1073T>G p.I358S | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV52856234; called by muse, mutect2
- GTF2E1 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs144112214, COSV52202973; called by muse, mutect2, varscan2
- GTF3C1 | c.2833C>T p.R945C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373264912; called by muse, varscan2
- GUCY1B1 | c.1772C>T p.S591F | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV100025581; called by muse, mutect2, varscan2
- GUCY2D | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 57/83 reads (69%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV54694156; called by muse, mutect2, varscan2
- GUF1 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV55781173; called by muse, mutect2, varscan2
- GYS2 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.31); catalogued as rs1233947907, COSV53920102; called by muse, mutect2, varscan2
- HACL1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58253281; called by muse, mutect2, varscan2
- HAL | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 12/20 reads (60%) | catalogued as COSV54116230, COSV54116625; called by mutect2, varscan2
- HAP1 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.37); PolyPhen benign (0.131); catalogued as COSV57877238; called by muse, mutect2, varscan2
- HAX1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 67/103 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55166925; called by muse, mutect2, varscan2
- HCN3 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV64233156; called by mutect2, varscan2
- HDC | c.1402C>T p.R468* | Nonsense Mutation (SNP) | VAF 24/45 reads (53%) | catalogued as rs756593325, COSV51068224; called by muse, mutect2, varscan2
- HDGF | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 63/285 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV61975427, COSV61977111; called by muse, mutect2, varscan2
- HEATR1 | c.6035G>A p.S2012N | Missense Mutation (SNP) | VAF 54/78 reads (69%) | SIFT tolerated (0.27); PolyPhen benign (0.194); catalogued as rs142962546; called by muse, varscan2
- HECTD4 | c.5120T>C p.V1707A | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66386051; called by muse, mutect2, varscan2
- HELT | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.114); catalogued as COSV58819551, COSV58820549; called by muse, mutect2
- HELZ | c.4066C>T p.P1356S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.3); catalogued as rs749763290, COSV100698702; called by muse, mutect2, varscan2
- HEPN1 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.01); catalogued as COSV100005702; called by muse, mutect2, varscan2
- HEPN1 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs1470335860, COSV100005704; called by mutect2, varscan2
- HEXB | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.609); catalogued as rs369767559; called by muse, mutect2, varscan2
- HIVEP3 | c.5897G>A p.R1966K | Missense Mutation (SNP) | VAF 63/90 reads (70%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV56008905; called by muse, mutect2, varscan2
- HKDC1 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs767245818, COSV63575300, COSV63578586; called by muse, mutect2, varscan2
- HLA-DRA | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV66622459; called by muse, mutect2, varscan2
- HLA-DRB5 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV66612099; called by muse, mutect2
- HMGB2 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.133); catalogued as COSV56633076; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.802A>G p.N268D | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV61254705; called by muse, mutect2, varscan2
- HOOK1 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1369854267, COSV64617544; called by mutect2, varscan2
- HORMAD1 | c.878G>A p.S293N | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1208991193, COSV59270039; called by muse, mutect2, varscan2
- HRH1 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 73/110 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199720564, COSV67954946; called by muse, mutect2, varscan2
- HS1BP3 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs377682003; called by mutect2, varscan2
- HS6ST3 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100940665, COSV65006714; called by muse, mutect2, varscan2
- HSD17B7 | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV54417298; called by muse, mutect2, varscan2
- HSPA4L | c.1996G>A p.G666R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376346224, COSV99613354; called by mutect2, varscan2
- HSPA4L | c.1997G>A p.G666E | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56548865, COSV99612982; called by muse, mutect2, varscan2
- HSPG2 | c.11764G>A p.E3922K | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0.104); catalogued as COSV60827322; called by mutect2, varscan2
- HTR2B | c.1126A>C p.N376H | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51448837; called by muse, mutect2, varscan2
- HTR2B | c.838A>T p.K280* | Nonsense Mutation (SNP) | VAF 31/108 reads (29%) | catalogued as COSV51448846, COSV99295254; called by mutect2, varscan2
- HTR3B | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.258); catalogued as COSV52742476, COSV52742530; called by muse, mutect2, varscan2
- HYAL1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.94); catalogued as COSV56496526; called by muse, mutect2, varscan2
- HYDIN | c.6439C>T p.R2147C | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370204963; called by mutect2, varscan2
- ICA1 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 113/119 reads (95%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs748302837, COSV55576265; called by muse, mutect2, varscan2
- ICA1 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 42/45 reads (93%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55575596; called by muse, mutect2, varscan2
- IDH2 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 55/56 reads (98%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57468821; called by muse, mutect2, varscan2
- IDO1 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53712770; called by muse, mutect2, varscan2
- IFITM3 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 46/73 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101296784; called by muse, mutect2, varscan2
- IGFBPL1 | c.800G>A p.R267K | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66617706; called by muse, mutect2, varscan2
- IGFN1 | c.2792G>A p.S931N (on ENST00000295591 / NM_001367841.1; = p.S3388N on NM_001164586.2) | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as rs140314343; called by muse, mutect2, varscan2
- IGKV1-12 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as rs776940472; called by mutect2, varscan2
- IGSF1 | c.3554G>A p.G1185E | Missense Mutation (SNP) | VAF 75/76 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63835825, COSV63840811; called by muse, mutect2, varscan2
- IGSF10 | c.6839T>C p.F2280S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV56367089; called by muse, mutect2, varscan2
- IGSF5 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.815); catalogued as COSV66029065; called by mutect2, varscan2
- IKZF3 | c.8-1G>A p.X3_splice | Splice Site (SNP) | VAF 12/33 reads (36%) | catalogued as COSV53099261; called by muse, mutect2, varscan2
- IL12RB1 | c.1631C>T p.S544F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV74045431; called by muse, mutect2, varscan2
- IL18R1 | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs867487527, COSV52122470; called by muse, mutect2, varscan2
- IL1A | c.659A>G p.N220S | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.253); catalogued as COSV54518460; called by muse, mutect2, varscan2
- IL36RN | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV61010242; called by muse, mutect2, varscan2
- IL3RA | c.759G>A p.Q253= | Splice Region (SNP) | VAF 30/72 reads (42%) | catalogued as rs766170874, COSV100452326, COSV58429626; called by muse, varscan2
- IL4R | c.1898C>T p.P633L | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50138064; called by muse, mutect2, varscan2
- IL4R | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as COSV50138071; called by muse, mutect2, varscan2
- ILVBL | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289847615, COSV54617597, COSV54617804; called by muse, mutect2, varscan2
- IPO4 | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV55777728; called by muse, mutect2, varscan2
- IQCC | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT tolerated (0.34); PolyPhen benign (0.033); catalogued as rs1408010165, COSV52207250; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1058G>A p.G353E (on ENST00000485419 / NM_001197113.1; = p.G277E on NM_014575.3) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV61858003; called by muse, mutect2, varscan2
- IQCN | c.2851C>T p.R951W | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.958); catalogued as rs754066617, COSV62746876; called by muse, mutect2, varscan2
- IRAK2 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.283); catalogued as COSV56528329; called by muse, mutect2, varscan2
- IREB2 | c.2032C>T p.H678Y | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766036361, COSV51920154; called by muse, mutect2, varscan2
- IRF2BPL | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs771393712, COSV53145820; called by muse, mutect2, varscan2
- IRX1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV57357723; called by mutect2, varscan2
- IRX4 | c.512C>T p.T171I | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51470515; called by muse, mutect2, varscan2
- ISM2 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV53633683; called by muse, mutect2, varscan2
- ISM2 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.031); catalogued as COSV99376628; called by muse, mutect2, varscan2
- ISM2 | c.142-1G>A p.X48_splice | Splice Site (SNP) | VAF 25/61 reads (41%) | catalogued as COSV99376632; called by muse, mutect2, varscan2
- ITFG2 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 120/214 reads (56%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as COSV57388970, COSV57390102, COSV57391435; called by muse, mutect2, varscan2
- ITGA7 | c.2821C>T p.P941S (on ENST00000555728; = p.P897S on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs761196927, COSV57690984; called by muse, mutect2, varscan2
- ITGA7 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57691022; called by muse, mutect2, varscan2
- ITGA9 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs749762782, COSV53235090; called by mutect2, varscan2
- ITGAM | c.1471G>T p.V491L | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54933394; called by muse, mutect2, varscan2
- ITGB6 | c.922-1G>A p.X308_splice | Splice Site (SNP) | VAF 21/63 reads (33%) | catalogued as COSV51790411; called by muse, mutect2, varscan2
- ITIH5 | c.2792G>A p.G931E | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99036548; called by muse, mutect2, varscan2
- ITPR2 | c.6070A>G p.N2024D | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); catalogued as COSV67263870; called by muse, mutect2, varscan2
- ITPR2 | c.835A>T p.K279* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV67263877; called by mutect2, varscan2
- ITPR3 | c.2747C>T p.S916F | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV65405112; called by muse, mutect2, varscan2
- ITPRID1 | c.1106C>A p.T369N | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as COSV60069503, COSV60073915; called by muse, mutect2
- ITPRID1 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 50/54 reads (93%) | SIFT tolerated (0.56); PolyPhen benign (0.018); catalogued as COSV60069510; called by muse, varscan2
- IVL | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.071); catalogued as rs267598043; called by mutect2, varscan2
- JADE1 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 39/119 reads (33%) | catalogued as COSV56903837; called by muse, mutect2, varscan2
- JAKMIP2 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV54596724; called by muse, mutect2, varscan2
- JCAD | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as COSV64757716; called by muse, mutect2, varscan2
- JPH4 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as rs1208334149, COSV58109811; called by muse, mutect2, varscan2
- JUP | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781974007, COSV60276955; ClinVar: uncertain significance; called by mutect2, varscan2
- KANK4 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as rs149755007, COSV62985214; called by muse, mutect2, varscan2
- KCNB2 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73048713; called by muse, mutect2, varscan2
- KCNB2 | c.1846A>C p.T616P | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.894); catalogued as COSV73048714; called by muse, mutect2, varscan2
- KCNC3 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV65387264; called by mutect2, varscan2
- KCNC4 | c.1414G>A p.V472I | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770301734, COSV63924849; called by mutect2, varscan2
- KCNG2 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1280323581, COSV100301788; called by muse, mutect2, varscan2
- KCNK10 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as rs975992605, COSV100068530, COSV56638780; called by muse, mutect2, varscan2
- KCNK10 | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.72); catalogued as COSV56638797; called by mutect2, varscan2
- KCNQ2 | c.470G>A p.W157* | Nonsense Mutation (SNP) | VAF 32/65 reads (49%) | catalogued as COSV60431369; called by muse, mutect2, varscan2
- KCNV2 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 20/21 reads (95%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1379886188, COSV66055457, COSV66057704; called by muse, mutect2, varscan2
- KCTD17 | c.893C>T p.P298L (on ENST00000403888 / NM_001282684.1; = p.P274L on NM_024681.3) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.025); catalogued as rs1338743270, COSV60974396; called by muse, mutect2, varscan2
- KCTD3 | c.2011T>C p.F671L | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52063854; called by muse, varscan2
- KDM4B | c.683T>A p.F228Y | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99346379; called by muse, mutect2, varscan2
- KDM7A | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV50089985; called by muse, mutect2, varscan2
- KDR | c.3212G>A p.W1071* | Nonsense Mutation (SNP) | VAF 24/74 reads (32%) | catalogued as COSV55757183; called by muse, mutect2, varscan2
- KIAA0100 | c.576+2T>C p.X192_splice | Splice Site (SNP) | VAF 7/35 reads (20%) | catalogued as COSV66490279; called by muse, mutect2, varscan2
- KIAA1109 | c.13964C>T p.S4655L | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52661042; called by muse, mutect2, varscan2
- KIAA1549 | c.1712C>T p.S571F | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV54304018; called by muse, mutect2, varscan2
- KIAA1549L | c.4570C>G p.R1524G (on ENST00000321505; = p.R1821G on NM_012194.3) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV58580985; called by muse, mutect2, varscan2
- KIAA1614 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 84/118 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV62552213; called by muse, mutect2, varscan2
- KIAA1755 | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs566259308, COSV54080805; called by muse, mutect2, varscan2
- KIF14 | c.4844G>A p.G1615D | Missense Mutation (SNP) | VAF 54/81 reads (67%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs542837815, COSV66259656; called by muse, mutect2, varscan2
- KIF14 | c.614G>A p.R205K | Missense Mutation (SNP) | VAF 78/100 reads (78%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV66259663; called by muse, mutect2, varscan2
- KIF17 | c.1553C>T p.S518F | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.011); catalogued as COSV56115293; called by muse, mutect2, varscan2
- KIF1C | c.3016C>T p.P1006S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100297128; called by muse, mutect2
- KIF26B | c.2443G>A p.G815R | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs748699060, COSV63635972; called by muse, mutect2
- KIF3B | c.1407C>T p.A469= | Splice Region (SNP) | VAF 49/102 reads (48%) | catalogued as rs763440309, COSV65226719; called by muse, mutect2, varscan2
- KIF5B | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV56650416; called by muse, mutect2, varscan2
- KIF5C | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs764718591, COSV68479597; called by mutect2, varscan2
- KIF5C | c.2707C>T p.R903C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1017774533, COSV68479604; called by mutect2, varscan2
- KIF6 | c.1862G>A p.G621E | Missense Mutation (SNP) | VAF 81/162 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as COSV54665244; called by muse, mutect2, varscan2
- KIR2DL1 | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.521); catalogued as rs755534597, COSV52405494; called by muse, mutect2, varscan2
- KLHL18 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as COSV51743735; called by mutect2, varscan2
- KLHL32 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs1249426465, COSV65110245; called by muse, mutect2, varscan2
- KLKB1 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.16); catalogued as COSV52993674; called by muse, mutect2, varscan2
- KLKB1 | c.1763G>A p.G588E | Missense Mutation (SNP) | VAF 82/147 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.164); catalogued as COSV52993689; called by muse, mutect2, varscan2
- KLRC3 | c.397A>T p.K133* | Nonsense Mutation (SNP) | VAF 22/79 reads (28%) | catalogued as COSV67249763; called by mutect2, varscan2
- KMT2C | c.7336C>T p.P2446S | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV51274647; called by muse, mutect2, varscan2
- KMT5B | c.1561C>A p.P521T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV100430073, COSV58563337; called by mutect2, varscan2
- KNDC1 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100464727; called by muse, varscan2
- KNG1 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53975899; called by muse, mutect2, varscan2
- KPRP | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV64220857; called by muse, mutect2, varscan2
- KRT24 | c.981A>C p.Q327H | Missense Mutation (SNP) | VAF 85/185 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV52879396; called by muse, mutect2, varscan2
- KRT26 | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV59412510; called by muse, mutect2, varscan2
- KRT36 | c.791A>T p.D264V | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV60202350; called by muse, mutect2, varscan2
- KRT9 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.087); catalogued as rs143561490; called by muse, varscan2
- KRTAP10-2 | c.737G>A p.S246N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.335); catalogued as COSV59950214; called by muse, varscan2
- KRTAP10-2 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201871032; called by muse, varscan2
- KRTAP15-1 | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV61876948, COSV61877024; called by muse, mutect2, varscan2
- L3MBTL2 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.74); catalogued as COSV53431449; called by muse, mutect2, varscan2
- LAMA2 | c.3933G>A p.W1311* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV70337097; called by muse, varscan2
- LAMA2 | c.7207G>A p.D2403N | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141476898; called by mutect2, varscan2
1,766 further variants in this file (871 protein-altering or splice-affecting, 845 silent, 50 other) are not listed here.
